Somatic mutation profile of tumor specimen 0DIY69 from CCDI case PBBUUR, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Body of pancreas; Age at diagnosis: 9.8 years (3,588 days).
Specimen 0DIY69: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7b22858a-1708-4220-8c90-32d391f34da4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DIY5V (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0ee721d3-5d32-4974-bdd1-7dc75131fad3

The open-access MAF lists 5 somatic variants for this specimen: 3 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 2, Silent 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PRRG1 | c.401dup p.P135Tfs*3 | Frame Shift Ins (INS) | VAF 78/217 reads (36%) | catalogued as rs781858060, COSV66158042; called by mutect2, varscan2
- SLC6A3 | c.50C>T p.P17L | Missense Mutation (SNP) | VAF 103/420 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs369923764, COSV104373642; called by muse, mutect2, varscan2
- NTNG1 | c.772A>G p.T258A | Missense Mutation (SNP) | VAF 115/389 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ACTR3B | c.708C>G p.P236= | Silent (SNP) | VAF 75/597 reads (13%) | catalogued as COSV55452693; called by muse, mutect2, varscan2
- FAM151B | c.210C>T p.S70= | Silent (SNP) | VAF 122/570 reads (21%) | catalogued as rs200002361; called by muse, mutect2, varscan2
